Somatic mutation profile of tumor specimen MP2PRT-PAPHIG-TMP1-A (aliquot MP2PRT-PAPHIG-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPHIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (882 days).
Specimen MP2PRT-PAPHIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a542aa5f-258e-4182-9fd9-a62e2f3f3242.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHIG-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHIG-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8195b47-78b1-4e98-9b76-a96e974424e6

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 278/771 reads (36%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 194/511 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRSK2 | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 240/606 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57539690; called by muse, mutect2, varscan2
- CBL | c.1247G>C p.C416S | Missense Mutation (SNP) | VAF 170/458 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757456261, COSV50630179, COSV50657213, COSV99875605; called by muse, mutect2, varscan2
- CHAT | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 152/442 reads (34%) | catalogued as rs1458796820; called by muse, mutect2, varscan2
- COL14A1 | c.4974G>T p.E1658D | Missense Mutation (SNP) | VAF 214/501 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); catalogued as rs750810651, COSV52859027; called by muse, mutect2, varscan2
- CPEB1 | c.440G>A p.R147H (on ENST00000617958; = p.R87H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 251/666 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV55619431, COSV99917926; called by muse, mutect2, varscan2
- FOXB2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 148/389 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209607680, COSV65022871; called by muse, mutect2, varscan2
- GABRG3 | c.951C>A p.D317E | Missense Mutation (SNP) | VAF 239/643 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61529200; called by muse, mutect2, varscan2
- NPC1L1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 216/646 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200554468, COSV99212621; called by muse, varscan2
- OR51G2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 243/626 reads (39%) | catalogued as rs146466233; called by muse, mutect2
- TMPRSS6 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 245/596 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.386); catalogued as rs752163489, COSV104415970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13C | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 143/409 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs866109444; called by muse, mutect2, varscan2
- CEP104 | c.1022T>G p.L341R | Missense Mutation (SNP) | VAF 170/448 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.735); called by muse, varscan2
- SEMG1 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 262/740 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDHB7 | c.1629C>T p.S543= | Silent (SNP) | VAF 436/1253 reads (35%) | catalogued as COSV50755334; called by muse, mutect2, varscan2
- TRAF6 | c.819G>A p.L273= | Silent (SNP) | VAF 175/468 reads (37%) | called by muse, mutect2, varscan2
